Gene-level copy-number profile of tumor specimen ALCH-B259-TTP1-A from ALCHEMIST case ALCH-B259, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.5 years (23,569 days).
Specimen ALCH-B259-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e979fba8-2f1b-42a7-9137-4872fc84a499.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B259-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,756 have no estimate.
https://portal.gdc.cancer.gov/files/3a246bda-fd0b-491b-8a1d-01da57e0dd68

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 361; copy number 1: 24,351; copy number 2: 30,728; copy number 3: 1,204; copy number 4: 1,977; copy number 5: 77; copy number 6: 167; copy number 12: 1; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:1,101,260–1,113,399, 2 genes: AL031713.1, AL031598.1.
- chr16:32,454,612–32,460,362, 2 genes: AC138915.3, AC138915.1.
- chr16:32,635,673–32,678,831, 6 genes: AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.
- chr16:32,845,964–32,848,156, 2 genes: AC142086.2, IGHV2OR16-5.
- chr16:32,903,442–33,129,090, 13 genes: IGHV3OR16-15, IGHV3OR16-6, AC142086.6, AC142086.3, AC142086.5, IGHV1OR16-2, IGHV3OR16-10, AC142086.4, IGHV1OR16-4, IGHV3OR16-8, AC145350.2, AC145350.3, HERC2P8.
- chr16:75,218,988–75,228,197, 2 genes (within-gene range 0–1): CTRB1, AC009078.2.
- chr17:4,481,966–4,486,353, 1 gene (within-gene range 0–1): AC127521.1.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:30,724,982–30,731,202, 3 genes (within-gene range 0–1): AC127024.7, AC127024.3, AC127024.2.
- chr17:66,964,707–67,033,398, 3 genes (within-gene range 0–1): CACNG4, AC005544.1, AC005544.2.
- chr17:73,737,854–73,756,932, 1 gene (within-gene range 0–1): AC125421.1.
- chr18:50,968,019–51,085,045, 2 genes (within-gene range 0–1): AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 246 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:99,489,559–99,595,297, 6 genes, copy number 6: AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2.
- chr5:106,815,197–107,011,052, 1 gene, copy number 6: LINC01950.
- chr5:119,445,716–119,445,833, 1 gene, copy number 6: RNA5SP190.
- chr5:140,071,312–141,174,391, 71 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr5:141,150,022–141,159,061, 2 genes, copy number 6 (within-gene range 1–6): PCDHB6, PCDHB17P.
- chr5:155,013,755–155,199,252, 3 genes, copy number 5: KIF4B, AC010476.2, AC010476.1.
- chr5:171,359,117–171,457,626, 8 genes, copy number 5: RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912, NPM1, FGF18, AC093246.1.
- chr16:33,495,943–33,554,408, 2 genes, copy number 12–13: AC136944.5, AC136944.4.
- chr19:36,797,502–39,846,379, 152 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21,996. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
